Somatic mutation profile of tumor specimen MMRF_1953_1_BM_CD138pos (aliquot MMRF_1953_1_BM_CD138pos_T1_KBS5U_L05852) from MMRF case MMRF_1953, project MMRF-COMMPASS (Multiple Myeloma CoMMpass Study). Sex at birth: male; Vital status: Alive; Primary diagnosis: Multiple myeloma; Tissue or organ of origin: Bone marrow; Age at diagnosis: 63.0 years (23,021 days).
Specimen MMRF_1953_1_BM_CD138pos: Sample type: Primary Blood Derived Cancer - Bone Marrow; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Bone Marrow NOS.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 573af0bf-f017-40e2-9f97-a1721aea37f7.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen MMRF_1953_1_PB_Whole (Blood Derived Normal), aliquot MMRF_1953_1_PB_Whole_C2_KBS5U_L05828; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/0efee5c0-7731-4180-804e-25c878765a93

The open-access MAF lists 99 somatic variants for this specimen: 38 protein-altering or splice-affecting, 14 silent, 47 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 30, 3'UTR 27, Silent 14, Intron 12, 5'Flank 4, Nonsense Mutation 4, RNA 2, Frame Shift Del 2, 5'UTR 2, In Frame Ins 1, Splice Site 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- NRAS | c.181C>A p.Q61K | Missense Mutation (SNP) | VAF 30/76 reads (39%) | hotspot (GDC flag); SIFT deleterious (0.01); PolyPhen possibly damaging (0.709); catalogued as rs121913254, COSV54736310, COSV54743343, COSV54752117; ClinVar: not provided / uncertain significance / likely pathogenic / pathogenic / drug response; called by muse, mutect2, varscan2
- ABCC11 | c.296G>A p.W99* | Nonsense Mutation (SNP) | VAF 23/48 reads (48%) | catalogued as COSV62326502; called by muse, mutect2, varscan2
- FAM241B | c.119G>A p.G40D | Missense Mutation (SNP) | VAF 29/91 reads (32%) | SIFT tolerated (0.21); PolyPhen benign (0.317); catalogued as rs747969242; called by muse, mutect2, varscan2
- GADL1 | c.753A>T p.E251D | Missense Mutation (SNP) | VAF 20/61 reads (33%) | SIFT tolerated (1); PolyPhen benign (0.006); catalogued as rs144521116; called by muse, mutect2, varscan2
- GGACT | c.436C>T p.R146C | Missense Mutation (SNP) | VAF 23/54 reads (43%) | SIFT deleterious (0.05); PolyPhen possibly damaging (0.48); catalogued as rs192075410, COSV104426538; called by muse, mutect2, varscan2
- IGHV2-70 | c.314A>G p.N105S | Missense Mutation (SNP) | VAF 24/28 reads (86%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as rs372581706; called by muse, varscan2
- IGHV2-70 | c.112A>C p.T38P | Missense Mutation (SNP) | VAF 32/48 reads (67%) | SIFT deleterious (0); PolyPhen possibly damaging (0.547); catalogued as rs371123161; called by muse, varscan2
- LRRIQ1 | c.251C>T p.A84V | Missense Mutation (SNP) | VAF 61/138 reads (44%) | SIFT tolerated, low confidence (0.28); PolyPhen benign (0.001); catalogued as rs566713351; called by muse, mutect2, varscan2
- MCL1 | c.556C>T p.L186F | Missense Mutation (SNP) | VAF 72/153 reads (47%) | SIFT tolerated (0.07); PolyPhen benign (0.335); catalogued as rs974314258; called by muse, mutect2, varscan2
- NPNT | c.1582C>T p.R528* | Nonsense Mutation (SNP) | VAF 32/64 reads (50%) | catalogued as rs745380935; called by muse, mutect2, varscan2
- TMEM102 | c.1390G>A p.D464N | Missense Mutation (SNP) | VAF 21/49 reads (43%) | SIFT tolerated (0.39); PolyPhen benign (0.38); catalogued as rs574300860; called by muse, mutect2, varscan2
- ACAP2 | c.2012A>T p.D671V | Missense Mutation (SNP) | VAF 54/125 reads (43%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- AMOTL1 | c.2032C>A p.L678M | Missense Mutation (SNP) | VAF 19/62 reads (31%) | SIFT deleterious (0); PolyPhen probably damaging (0.982); called by muse, mutect2, varscan2
- BCKDHB | c.1039-1G>T p.X347_splice | Splice Site (SNP) | VAF 6/83 reads (7%) | called by muse, mutect2
- BCKDHB | c.1039G>T p.E347* | Nonsense Mutation (SNP) | VAF 6/86 reads (7%) | called by muse, mutect2
- BCL9 | c.61A>G p.K21E | Missense Mutation (SNP) | VAF 26/62 reads (42%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.978); called by muse, mutect2, varscan2
- CNTROB | c.2552C>A p.T851K | Missense Mutation (SNP) | VAF 33/92 reads (36%) | SIFT deleterious, low confidence (0.04); PolyPhen benign (0.159); called by muse, mutect2, varscan2
- DAG1 | c.1337_1339dup p.T446_R447insP | In Frame Ins (INS) | VAF 105/237 reads (44%) | called by mutect2, pindel, varscan2
- EGF | c.2260C>T p.H754Y | Missense Mutation (SNP) | VAF 33/111 reads (30%) | SIFT deleterious (0); PolyPhen possibly damaging (0.558); called by muse, mutect2, varscan2
- ELP2 | c.16C>A p.L6M | Missense Mutation (SNP) | VAF 15/218 reads (7%) | SIFT deleterious (0.04); PolyPhen benign (0.111); called by muse, mutect2
- HIC1 | c.1493G>T p.G498V (on ENST00000322941 / NM_001098202.1; = p.G479V on NM_006497.4) | Missense Mutation (SNP) | VAF 21/63 reads (33%) | SIFT tolerated (0.34); PolyPhen benign (0.019); called by muse, mutect2, varscan2
- IGLV7-46 | c.40T>G p.C14G | Missense Mutation (SNP) | VAF 54/124 reads (44%) | SIFT tolerated (0.21); PolyPhen benign (0.007); called by muse, mutect2, varscan2
- IMPG1 | c.1142C>T p.A381V | Missense Mutation (SNP) | VAF 40/122 reads (33%) | SIFT tolerated (1); PolyPhen benign (0); called by muse, mutect2, varscan2
- ISM1 | c.319C>A p.L107I | Missense Mutation (SNP) | VAF 67/157 reads (43%) | SIFT deleterious (0.01); PolyPhen benign (0.019); called by muse, mutect2, varscan2
- KRT76 | c.1260del p.K420Nfs*52 | Frame Shift Del (DEL) | VAF 20/54 reads (37%) | called by mutect2, pindel*, varscan2
- LAMA1 | c.3854A>C p.Q1285P | Missense Mutation (SNP) | VAF 10/52 reads (19%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.577); called by muse, mutect2, varscan2
- MAPK7 | c.123A>T p.K41N | Missense Mutation (SNP) | VAF 4/87 reads (5%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.991); called by muse, mutect2
- NEURL4 | c.1010C>T p.A337V | Missense Mutation (SNP) | VAF 31/65 reads (48%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- NPSR1 | c.509C>T p.A170V | Missense Mutation (SNP) | VAF 26/52 reads (50%) | SIFT deleterious (0); PolyPhen probably damaging (0.926); called by muse, mutect2, varscan2
- OTX2 | c.786A>T p.Q262H (on ENST00000408990 / NM_172337.3; = p.Q270H on NM_021728.4) | Missense Mutation (SNP) | VAF 28/72 reads (39%) | SIFT deleterious (0.05); PolyPhen probably damaging (0.935); called by muse, mutect2, varscan2
- PCDH10 | c.157T>A p.F53I | Missense Mutation (SNP) | VAF 49/95 reads (52%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.993); called by muse, mutect2, varscan2
- PCDH7 | c.665C>T p.S222F | Missense Mutation (SNP) | VAF 10/26 reads (38%) | SIFT tolerated (0.64); PolyPhen benign (0.017); called by muse, mutect2, varscan2
- PXDN | c.3189C>A p.N1063K | Missense Mutation (SNP) | VAF 36/98 reads (37%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- RBAK | c.76G>A p.D26N | Missense Mutation (SNP) | VAF 34/111 reads (31%) | SIFT tolerated (0.16); PolyPhen benign (0.125); called by muse, mutect2, varscan2
- SPECC1L | c.101C>A p.A34E | Missense Mutation (SNP) | VAF 55/160 reads (34%) | SIFT tolerated (0.09); PolyPhen benign (0.088); called by muse, mutect2, varscan2
- TENT5C | c.874del p.L292Ffs*17 | Frame Shift Del (DEL) | VAF 38/119 reads (32%) | called by mutect2, pindel, varscan2
- TRIM10 | c.1093C>T p.H365Y | Missense Mutation (SNP) | VAF 8/147 reads (5%) | SIFT tolerated (0.08); PolyPhen probably damaging (0.986); called by muse, mutect2
- ZNF92 | c.189G>A p.W63* | Nonsense Mutation (SNP) | VAF 26/299 reads (9%) | called by muse, mutect2
- ANO3 | c.1212A>G p.G404= | Silent (SNP) | VAF 59/161 reads (37%) | called by muse, mutect2, varscan2
- ATP9A | c.933G>T p.L311= | Silent (SNP) | VAF 25/69 reads (36%) | called by muse, mutect2, varscan2
- CEACAM5 | c.1860C>T p.N620= | Silent (SNP) | VAF 51/111 reads (46%) | catalogued as rs928190611; called by muse, mutect2, varscan2
- ENC1 | c.1233A>G p.L411= | Silent (SNP) | VAF 36/124 reads (29%) | called by muse, mutect2, varscan2
- FRMPD2 | c.2559A>T p.I853= | Silent (SNP) | VAF 37/114 reads (32%) | called by muse, mutect2, varscan2
- H2BC10 | c.318G>A p.E106= | Silent (SNP) | VAF 38/99 reads (38%) | called by muse, mutect2, varscan2
- HNMT | c.450C>T p.D150= | Silent (SNP) | VAF 30/75 reads (40%) | called by muse, mutect2, varscan2
- IGLV7-46 | c.90T>C p.T30= | Silent (SNP) | VAF 20/56 reads (36%) | called by muse, varscan2
- ITPKB | c.2838C>G p.A946= | Silent (SNP) | VAF 19/72 reads (26%) | called by muse, mutect2, varscan2
- MARF1 | c.1495T>C p.L499= | Silent (SNP) | VAF 42/92 reads (46%) | called by muse, mutect2, varscan2
- SLC24A2 | c.417C>T p.V139= | Silent (SNP) | VAF 12/105 reads (11%) | called by muse, mutect2, varscan2
- SLC37A3 | c.822T>C p.S274= | Silent (SNP) | VAF 48/125 reads (38%) | catalogued as COSV58262929; called by muse, mutect2, varscan2
- TENT5C | c.405G>A p.K135= | Silent (SNP) | VAF 5/132 reads (4%) | catalogued as rs1347618249; called by muse, mutect2
- TJP3 | c.2142G>A p.A714= | Silent (SNP) | VAF 36/119 reads (30%) | catalogued as rs763775558; called by muse, mutect2, varscan2
- AC093802.1 | n.1914+9221G>A | Intron (SNP) | VAF 23/59 reads (39%) | called by muse, mutect2, varscan2
- AJAP1 | c.*40C>T | 3'UTR (SNP) | VAF 57/180 reads (32%) | catalogued as rs761895709, COSV65454705; called by muse, mutect2
- AL158077.1 | n.45C>A | RNA (SNP) | VAF 12/35 reads (34%) | called by muse, mutect2, varscan2
- ANTXR1 | c.952-6690G>C | Intron (SNP) | VAF 23/64 reads (36%) | called by muse, mutect2, varscan2
- ARID1B | c.2840+50G>C | Intron (SNP) | VAF 8/22 reads (36%) | called by muse, mutect2, varscan2
- BCL7A | chr12:122021372 G>C | 5'Flank (SNP) | VAF 34/70 reads (49%) | catalogued as COSV55847988; called by muse, mutect2, varscan2
- BMP6 | c.*1178_*1197del | 3'UTR (DEL) | VAF 32/111 reads (29%) | called by mutect2, pindel, varscan2
- CACNA2D2 | chr3:50503608 C>T | 5'Flank (SNP) | VAF 7/15 reads (47%) | catalogued as rs867581167; called by muse, mutect2, varscan2
- CBLB | c.*1082A>C | 3'UTR (SNP) | VAF 39/90 reads (43%) | called by muse, mutect2, varscan2
- CSF2RB | c.*918C>T | 3'UTR (SNP) | VAF 3/43 reads (7%) | called by muse, mutect2
- DCT | c.595+9T>A | Intron (SNP) | VAF 70/200 reads (35%) | called by muse, mutect2, varscan2
- DDIT4L | c.*1495A>G | 3'UTR (SNP) | VAF 29/90 reads (32%) | catalogued as rs996763487; called by muse, mutect2, varscan2
- EGR1 | c.-94C>G | 5'UTR (SNP) | VAF 6/16 reads (38%) | catalogued as COSV53521276; called by muse, mutect2, varscan2
- EPHA5 | c.*3174C>A | 3'UTR (SNP) | VAF 32/82 reads (39%) | called by muse, mutect2, varscan2
- FOXL2NB | c.*108C>T | 3'UTR (SNP) | VAF 55/165 reads (33%) | called by muse, mutect2, varscan2
- FUT4 | c.*784G>A | 3'UTR (SNP) | VAF 14/34 reads (41%) | called by muse, mutect2, varscan2
- GRM7 | c.*1032dup | 3'UTR (INS) | VAF 36/104 reads (35%) | called by mutect2, varscan2
- IL1RAP | c.*1460A>C | 3'UTR (SNP) | VAF 11/25 reads (44%) | called by muse, mutect2, varscan2
- ITIH1 | c.305+17C>T | Intron (SNP) | VAF 17/42 reads (40%) | catalogued as rs1229760992; called by muse, mutect2, varscan2
- ITPKB | c.*179G>C | 3'UTR (SNP) | VAF 32/136 reads (24%) | called by muse, mutect2, varscan2
- ITSN1 | c.*6416T>G | 3'UTR (SNP) | VAF 17/47 reads (36%) | called by muse, mutect2, varscan2
- LINC01555 | n.1989G>A | RNA (SNP) | VAF 43/109 reads (39%) | catalogued as rs113337116; called by muse, mutect2, varscan2
- LMO2 | c.-89C>T | 5'UTR (SNP) | VAF 10/23 reads (43%) | called by muse, mutect2, varscan2
- LRCOL1 | c.105+64C>T | Intron (SNP) | VAF 12/27 reads (44%) | catalogued as rs908127984; called by muse, mutect2, varscan2
- LUZP1 | c.3072+752C>A | Intron (SNP) | VAF 8/12 reads (67%) | called by muse, mutect2, varscan2
- MEGF10 | c.*20A>G | 3'UTR (SNP) | VAF 24/63 reads (38%) | called by muse, mutect2, varscan2
- MR1 | c.*157A>C | 3'UTR (SNP) | VAF 50/145 reads (34%) | called by muse, mutect2, varscan2
- MSR1 | c.1033+3418T>G | Intron (SNP) | VAF 22/40 reads (55%) | called by muse, mutect2, varscan2
- NAT16 | c.*918G>A | 3'UTR (SNP) | VAF 53/170 reads (31%) | called by muse, mutect2, varscan2
- NCKAP5 | c.341+7042A>G | Intron (SNP) | VAF 33/60 reads (55%) | called by muse, mutect2, varscan2
- NR3C2 | c.*632A>G | 3'UTR (SNP) | VAF 57/140 reads (41%) | called by muse, mutect2, varscan2
- PCDH17 | c.*3055C>A | 3'UTR (SNP) | VAF 18/45 reads (40%) | catalogued as rs368039381; called by muse, mutect2, varscan2
- PDGFRA | c.*160A>G | 3'UTR (SNP) | VAF 16/48 reads (33%) | called by muse, mutect2, varscan2
- POLR2C | c.387+20C>G | Intron (SNP) | VAF 52/127 reads (41%) | called by muse, mutect2
- PRKAB1 | chr12:119667887 C>A | 5'Flank (SNP) | VAF 27/93 reads (29%) | called by muse, mutect2, varscan2
- PXDN | c.*562G>C | 3'UTR (SNP) | VAF 36/95 reads (38%) | called by muse, mutect2, varscan2
- RTF1 | c.*1855del | 3'UTR (DEL) | VAF 20/44 reads (45%) | catalogued as rs397854563; called by mutect2, varscan2
- SIDT2 | c.2437-21G>A | Intron (SNP) | VAF 19/230 reads (8%) | called by muse, mutect2
- SLC2A11 | chr22:23856688 A>T | 5'Flank (SNP) | VAF 15/38 reads (39%) | called by muse, mutect2, varscan2
- SLC6A7 | c.*806G>C | 3'UTR (SNP) | VAF 17/47 reads (36%) | called by muse, mutect2, varscan2
- STEAP4 | c.*1102A>G | 3'UTR (SNP) | VAF 39/99 reads (39%) | catalogued as rs1184376194; called by muse, mutect2, varscan2
- STXBP4 | c.*4218A>T | 3'UTR (SNP) | VAF 54/130 reads (42%) | called by muse, mutect2, varscan2
- SYTL1 | c.633+63C>G | Intron (SNP) | VAF 19/43 reads (44%) | called by muse, mutect2, varscan2
- TAF5L | c.*520del | 3'UTR (DEL) | VAF 28/66 reads (42%) | catalogued as rs1372563652; called by mutect2, varscan2
- VASH1 | c.*438G>A | 3'UTR (SNP) | VAF 46/128 reads (36%) | catalogued as rs370722585; called by muse, mutect2, varscan2
- VGLL3 | c.*4909_*4910del | 3'UTR (DEL) | VAF 16/57 reads (28%) | called by mutect2, pindel, varscan2
- ZNF142 | c.*1620_*1623del | 3'UTR (DEL) | VAF 106/297 reads (36%) | called by mutect2, pindel, varscan2
